Somatic mutation profile of tumor specimen ALCH-B02L-TTP1-A (aliquot ALCH-B02L-TTP1-A-1-0-D-A679-36) from ALCHEMIST case ALCH-B02L, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.2 years (23,432 days).
Specimen ALCH-B02L-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce179487-f728-4866-918c-12e1a2852d66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B02L-NB1-A (Blood Derived Normal), aliquot ALCH-B02L-NB1-A-2-0-D-A679-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7853e56f-5152-469d-a27e-ce8126d19019

The open-access MAF lists 452 somatic variants for this specimen: 305 protein-altering or splice-affecting, 86 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 258, Silent 86, Intron 29, Nonsense Mutation 26, Splice Site 12, RNA 12, 3'UTR 9, Frame Shift Del 6, 5'Flank 4, 5'UTR 4, 3'Flank 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAD51D | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 30/626 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs544654228; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- TP53 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 352/644 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1131691025, COSV52677105, COSV52952688; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC10 | c.619G>T p.E207* (on ENST00000372530 / NM_001198934.2; = p.E164* on NM_033450.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 29/209 reads (14%) | catalogued as COSV55084462; called by muse, mutect2, varscan2
- ADCY9 | c.3259G>C p.E1087Q | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53579003; called by muse, mutect2, varscan2
- AGTR1 | c.814C>A p.R272S | Missense Mutation (SNP) | VAF 79/490 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV62559064; called by muse, mutect2, varscan2
- ALX4 | c.377G>C p.R126P | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as rs1404064476, COSV61328917, COSV61329449; called by muse, mutect2, varscan2
- AMPD1 | c.1428C>A p.F476L | Missense Mutation (SNP) | VAF 152/565 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV62415554, COSV62415706, COSV62416040; called by muse, mutect2, varscan2
- ARHGAP29 | c.1702C>G p.P568A | Missense Mutation (SNP) | VAF 14/422 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.837); catalogued as COSV53112135; called by muse, mutect2
- ARHGAP42 | c.1265A>C p.N422T | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs746843175; called by muse, mutect2, varscan2
- ATP1A4 | c.2179G>T p.D727Y | Missense Mutation (SNP) | VAF 81/271 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63626664; called by muse, mutect2, varscan2
- BSN | c.1285C>G p.L429V | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.191); catalogued as COSV56523081; called by muse, mutect2, varscan2
- CCNE1 | c.945G>T p.K315N | Missense Mutation (SNP) | VAF 89/325 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as rs1333385090; called by muse, mutect2, varscan2
- CDH10 | c.2293C>A p.L765I | Missense Mutation (SNP) | VAF 164/323 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52598784; called by muse, mutect2, varscan2
- CDH12 | c.2296G>T p.D766Y | Missense Mutation (SNP) | VAF 261/542 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV66447573; called by muse, mutect2, varscan2
- CDH22 | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64838261; called by muse, mutect2, varscan2
- CEP126 | c.1879A>G p.I627V | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0.073); catalogued as COSV54832161; called by muse, mutect2, varscan2
- CEP128 | c.2024G>T p.R675M | Missense Mutation (SNP) | VAF 69/205 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.326); catalogued as COSV99823902; called by muse, mutect2, varscan2
- COL11A1 | c.1571G>T p.R524L | Missense Mutation (SNP) | VAF 158/597 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62174687; called by muse, mutect2, varscan2
- COL19A1 | c.1232G>T p.R411L | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100507126; called by muse, mutect2, varscan2
- DCAF12 | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs376139003; called by muse, mutect2, varscan2
- DCC | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 129/620 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs769007732; called by muse, mutect2, varscan2
- DNAH9 | c.11845G>T p.A3949S | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); catalogued as rs112402185, COSV99306107; called by muse, mutect2
- DRP2 | c.1988G>T p.S663I | Missense Mutation (SNP) | VAF 107/159 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV65812436; called by muse, mutect2, varscan2
- EDAR | c.877G>C p.D293H | Missense Mutation (SNP) | VAF 9/284 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV51499574; called by muse, mutect2
- EPB41L3 | c.1415A>G p.K472R | Missense Mutation (SNP) | VAF 46/660 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs747269632; called by muse, mutect2
- EYS | c.99T>A p.H33Q | Missense Mutation (SNP) | VAF 60/412 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as rs1050556768; called by muse, mutect2, varscan2
- FAM117A | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 96/334 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.783); catalogued as COSV53633430; called by muse, mutect2, varscan2
- FANCM | c.2953G>A p.E985K | Missense Mutation (SNP) | VAF 27/392 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV99951621; called by muse, mutect2
- FBXL17 | c.2057G>T p.R686I | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780438502; called by muse, mutect2, varscan2
- FFAR3 | c.564G>T p.M188I | Missense Mutation (SNP) | VAF 216/1400 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100588226; called by muse, varscan2
- FPR1 | c.570G>T p.R190S | Missense Mutation (SNP) | VAF 96/264 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.219); catalogued as COSV59053986; called by muse, mutect2, varscan2
- GJA10 | c.1075G>T p.G359C | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV65356397; called by muse, mutect2, varscan2
- GPA33 | c.345C>A p.Y115* | Nonsense Mutation (SNP) | VAF 225/724 reads (31%) | catalogued as rs146226279; called by muse, mutect2, varscan2
- GRIK5 | c.2830G>T p.A944S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as rs1432915592; called by muse, mutect2, varscan2
- HDAC4 | c.155G>T p.R52L | Missense Mutation (SNP) | VAF 130/188 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs777568201, COSV61861923; called by muse, mutect2, varscan2
- HELZ2 | c.7281G>T p.M2427I (on ENST00000467148 / NM_001037335.2; = p.M1858I on NM_033405.3) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1222635654, COSV64443342; called by muse, mutect2
- HES7 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs1308150151; called by muse, mutect2
- IL4R | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs151179009; called by muse, mutect2
- INHBB | c.812C>G p.S271W | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54677954; called by muse, mutect2
- INSR | c.829G>T p.D277Y | Missense Mutation (SNP) | VAF 91/472 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV57157020; called by muse, mutect2, varscan2
- JAK2 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs368927897, CM1111733, COSV67590089, COSV67606947; called by muse, mutect2, varscan2
- KDM3B | c.3496G>A p.G1166R | Missense Mutation (SNP) | VAF 109/383 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.642); catalogued as rs1450753127; called by muse, mutect2, varscan2
- KIAA0319 | c.2674C>T p.R892W | Missense Mutation (SNP) | VAF 46/623 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as rs557734049, COSV65497295; called by muse, mutect2
- LDHAL6B | c.152C>A p.A51E | Missense Mutation (SNP) | VAF 84/430 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV55692409; called by muse, mutect2, varscan2
- LMBRD1 | c.1670C>T p.P557L (on ENST00000649011; = p.P535L on NM_018368.4) | Missense Mutation (SNP) | VAF 224/488 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs774967890, COSV65297821; called by muse, mutect2, varscan2
- LMBRD1 | c.1372G>T p.V458F (on ENST00000649011; = p.V436F on NM_018368.4) | Missense Mutation (SNP) | VAF 111/228 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV65298134; called by muse, mutect2, varscan2
- LRP1B | c.9193C>T p.P3065S | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.062); catalogued as rs772868995; called by muse, mutect2, varscan2
- MDGA2 | c.1520G>T p.S507I (on ENST00000399232 / NM_001113498.2; = p.S209I on NM_182830.4) | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV62093355; called by muse, mutect2
- MPPED2 | c.537-1G>T p.X179_splice | Splice Site (SNP) | VAF 44/194 reads (23%) | catalogued as COSV100813157, COSV63897386; called by muse, mutect2, varscan2
- MRGPRX4 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.416); catalogued as rs765447552; called by muse, mutect2, varscan2
- MYO1A | c.1790G>T p.R597L | Missense Mutation (SNP) | VAF 361/634 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as rs754238164, COSV55655387; called by muse, mutect2, varscan2
- MYOC | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 171/663 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs144579767, COSV50675587; called by muse, mutect2, varscan2
- MYOCD | c.2243G>T p.G748V | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100590242; called by muse, mutect2, varscan2
- NBAS | c.4232C>G p.T1411S | Missense Mutation (SNP) | VAF 54/389 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.288); catalogued as rs1475390960; called by muse, varscan2
- NKX1-1 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious, low confidence (0); catalogued as COSV70026372; called by muse, mutect2
- NLN | c.1200G>C p.L400F | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV66765104; called by muse, mutect2
- NRG3 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated (1); PolyPhen possibly damaging (0.478); catalogued as COSV64568833; called by muse, mutect2
- NRXN2 | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770514271; called by muse, mutect2, varscan2
- NSD1 | c.3154C>T p.R1052C | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs748956033; ClinVar: likely benign; called by muse, mutect2
- OR1E2 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 187/335 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs770883252; called by muse, mutect2, varscan2
- OR5D16 | c.424C>T p.L142F | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.293); catalogued as rs748313251; called by muse, mutect2, varscan2
- PADI3 | c.916C>A p.L306I | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs1431725456; called by muse, mutect2, varscan2
- PATJ | c.3670+1G>T p.X1224_splice | Splice Site (SNP) | VAF 57/173 reads (33%) | catalogued as COSV100334416, COSV57164037; called by muse, mutect2, varscan2
- PCLO | c.6973G>T p.E2325* | Nonsense Mutation (SNP) | VAF 87/341 reads (26%) | catalogued as COSV61668359; called by muse, mutect2, varscan2
- PDGFRA | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 31/511 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV57274430; called by muse, mutect2
- PKHD1 | c.6217G>T p.G2073W | Missense Mutation (SNP) | VAF 151/482 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV100580952; called by muse, mutect2, varscan2
- RBM15 | c.2059G>T p.D687Y | Missense Mutation (SNP) | VAF 62/504 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63923951; called by muse, mutect2, varscan2
- REG1A | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 143/579 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); catalogued as COSV52069246, COSV99286659; called by muse, mutect2, varscan2
- RET | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 119/454 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.903); catalogued as rs759229505, COSV60704547; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RUNX3 | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1338525855, COSV58243361, COSV58243531; called by muse, mutect2, varscan2
- RYR2 | c.6850G>T p.G2284C | Missense Mutation (SNP) | VAF 117/512 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as rs1358347233, COSV63710725; called by muse, mutect2, varscan2
- SEPTIN14 | c.210C>A p.D70E | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.803); catalogued as COSV66430015; called by muse, mutect2, varscan2
- SLC14A1 | c.1152G>T p.M384I | Missense Mutation (SNP) | VAF 77/507 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs747819432; called by muse, mutect2, varscan2
- SLC23A3 | c.125C>G p.S42C | Missense Mutation (SNP) | VAF 38/549 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as COSV55406839, COSV55407985; called by muse, mutect2
- SOHLH1 | c.194G>C p.R65P | Missense Mutation (SNP) | VAF 103/249 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV100039992, COSV53681013; called by muse, mutect2, varscan2
- SPAG6 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 19/190 reads (10%) | catalogued as rs779459381, COSV57619778; called by muse, mutect2, varscan2
- SPAG9 | c.3746C>G p.T1249R (on ENST00000262013 / NM_001130528.3; = p.T1235R on NM_003971.6) | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.086); catalogued as COSV100004591; called by muse, mutect2
- SPHKAP | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 13/342 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs1487343994; called by muse, mutect2
- SRRM2 | c.6698C>T p.P2233L | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99241665; called by muse, mutect2, varscan2
- TENT5C | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 121/492 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65616038, COSV65617398; called by muse, mutect2, varscan2
- TMEM87B | c.1185T>A p.F395L | Missense Mutation (SNP) | VAF 24/323 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs774828905, COSV51714424; called by muse, mutect2
- TMPRSS13 | c.622G>C p.A208P | Missense Mutation (SNP) | VAF 186/516 reads (36%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.976); catalogued as COSV101471474, COSV101471512; called by muse, mutect2, varscan2
- TOP2A | c.1015G>C p.D339H | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV70732422; called by muse, mutect2
- TRIM49B | c.681A>T p.R227S | Missense Mutation (SNP) | VAF 97/484 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs771955712; called by muse, mutect2, varscan2
- TRIM60 | c.600G>T p.M200I | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100594191; called by muse, mutect2, varscan2
- TYRP1 | c.610G>T p.G204* | Nonsense Mutation (SNP) | VAF 16/229 reads (7%) | catalogued as COSV66358615; called by muse, mutect2
- UNC13C | c.5530G>A p.V1844I | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs377334158; called by muse, mutect2, varscan2
- UNC80 | c.2608A>G p.M870V | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.915); catalogued as rs1257866838; called by muse, mutect2
- USP48 | c.941A>T p.Y314F | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57607467; called by muse, mutect2, varscan2
- XCL1 | c.138G>T p.K46N | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs1449324534, COSV63191765; called by muse, varscan2
- ZBTB20 | c.832C>T p.R278C (on ENST00000474710 / NM_001164342.2; = p.R205C on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs11541118; called by muse, mutect2, varscan2
- ZFR | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs1361134933; called by muse, mutect2
- ZNF391 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 19/243 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769108204, COSV99772714; called by muse, mutect2
- ZNF536 | c.2985G>T p.Q995H | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV100835316, COSV62833445; called by muse, mutect2
- ZNF564 | c.316A>T p.S106C | Missense Mutation (SNP) | VAF 19/222 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV59434172; called by muse, mutect2
- ZNF626 | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs145508356, COSV52482538; called by muse, mutect2, varscan2
- ZNF800 | c.790A>T p.I264F | Missense Mutation (SNP) | VAF 98/299 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV99758255; called by muse, mutect2, varscan2
- ZSWIM8 | c.4105G>T p.A1369S (on ENST00000605216 / NM_001242487.2; = p.A1374S on NM_015037.3) | Missense Mutation (SNP) | VAF 106/381 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV55213181; called by muse, mutect2, varscan2
- AACS | c.1152G>T p.W384C | Missense Mutation (SNP) | VAF 160/575 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- ABCC1 | c.1539A>T p.K513N | Missense Mutation (SNP) | VAF 67/467 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACD | c.124G>C p.A42P | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACOX3 | c.703A>T p.T235S | Missense Mutation (SNP) | VAF 53/460 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ACSM2A | c.1142G>A p.G381E (on ENST00000219054; = p.G302E on NM_001308169.2) | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGB | c.1088-1G>T p.X363_splice | Splice Site (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2
- ADGRF4 | c.1418G>T p.C473F | Missense Mutation (SNP) | VAF 168/398 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGMO | c.1153C>A p.Q385K | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AGXT | c.665T>G p.F222C | Missense Mutation (SNP) | VAF 13/331 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AKAIN1 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- AKAP6 | c.2440G>A p.D814N | Missense Mutation (SNP) | VAF 25/510 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- ALMS1 | c.9055G>T p.V3019L | Missense Mutation (SNP) | VAF 107/464 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AMY2A | c.313G>T p.G105W | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.2797-1G>T p.X933_splice | Splice Site (SNP) | VAF 154/421 reads (37%) | called by muse, mutect2, varscan2
- ANO10 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 97/309 reads (31%) | called by muse, mutect2, varscan2
- AQP2 | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ATP2B4 | c.1261G>T p.V421L | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- BTBD11 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 47/80 reads (59%) | called by muse, mutect2, varscan2
- C18orf54 | c.1011G>T p.K337N | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- C18orf54 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 24/117 reads (21%) | called by muse, mutect2, varscan2
- C1QA | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 167/600 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CALHM2 | c.287C>A p.A96D | Missense Mutation (SNP) | VAF 151/515 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CATSPER1 | c.1144C>G p.H382D | Missense Mutation (SNP) | VAF 63/728 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- CBY3 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by mutect2, varscan2
- CCDC12 | c.274G>T p.A92S (on ENST00000425441 / NM_001277074.1; = p.A105S on NM_144716.5) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.288); called by muse, varscan2
- CCDC149 | c.1339C>T p.Q447* (on ENST00000635206 / NM_001330643.2; = p.Q436* on NM_173463.5) | Nonsense Mutation (SNP) | VAF 314/785 reads (40%) | called by muse, mutect2, varscan2
- CCDC50 | c.412_413delinsT p.R138Lfs*40 (on ENST00000392455 / NM_178335.3; = p.R138Lfs*14 on NM_174908.4) | Frame Shift Del (DEL) | VAF 45/362 reads (12%) | called by pindel, varscan2*
- CCDC51 | c.1062C>A p.D354E | Missense Mutation (SNP) | VAF 30/420 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2
- CD36 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2
- CDC14C | c.350G>T p.R117L (on ENST00000428251; = p.R10L on NM_152627.3) | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CDH17 | c.2485C>T p.P829S | Missense Mutation (SNP) | VAF 87/533 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CFAP77 | c.531C>A p.Y177* | Nonsense Mutation (SNP) | VAF 16/568 reads (3%) | called by muse, mutect2
- CHST1 | c.547C>A p.R183S | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CLCNKA | c.1543T>A p.C515S | Missense Mutation (SNP) | VAF 124/501 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CLSPN | c.2948G>C p.G983A | Missense Mutation (SNP) | VAF 78/256 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CMTR1 | c.2255G>A p.R752K | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CNTNAP2 | c.1598T>A p.L533* | Nonsense Mutation (SNP) | VAF 63/254 reads (25%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.2186C>A p.A729D | Missense Mutation (SNP) | VAF 180/799 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- COL12A1 | c.2593A>C p.T865P | Missense Mutation (SNP) | VAF 52/535 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- CROCC | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 42/360 reads (12%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CSDE1 | c.2113G>T p.V705F (on ENST00000358528 / NM_001007553.3; = p.V674F on NM_007158.6) | Missense Mutation (SNP) | VAF 25/416 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- CUX2 | c.4351G>T p.V1451L | Missense Mutation (SNP) | VAF 16/376 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- CYP2E1 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 99/343 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DEPDC5 | c.3628G>T p.A1210S (on ENST00000400246; = p.A1279S on NM_014662.5) | Missense Mutation (SNP) | VAF 120/661 reads (18%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- DIDO1 | c.2619del p.K873Nfs*11 | Frame Shift Del (DEL) | VAF 28/202 reads (14%) | called by mutect2, pindel, varscan2
- DLC1 | c.589A>T p.I197L | Missense Mutation (SNP) | VAF 95/253 reads (38%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMGDH | c.1712T>C p.L571S | Missense Mutation (SNP) | VAF 73/250 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DNAL4 | c.260A>C p.N87T | Missense Mutation (SNP) | VAF 75/182 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- DNER | c.617G>T p.S206I | Missense Mutation (SNP) | VAF 173/499 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DOCK10 | c.5096G>T p.R1699L | Missense Mutation (SNP) | VAF 408/698 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DST | c.2919G>T p.M973I (on ENST00000361203 / NM_001374722.1; = p.M647I on NM_001723.6) | Missense Mutation (SNP) | VAF 62/394 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- DUSP10 | c.690del p.E232Kfs*3 | Frame Shift Del (DEL) | VAF 120/416 reads (29%) | called by mutect2, varscan2
- DUSP10 | c.689C>A p.S230Y | Missense Mutation (SNP) | VAF 129/416 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.07); called by mutect2, varscan2
- DUXB | c.421C>G p.L141V | Missense Mutation (SNP) | VAF 19/328 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.043); called by muse, mutect2
- DVL3 | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- DYNC1I1 | c.746C>A p.S249Y | Missense Mutation (SNP) | VAF 16/491 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- DYNC1LI1 | c.1411G>T p.G471C | Missense Mutation (SNP) | VAF 111/450 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- EDAR | c.878A>T p.D293V | Missense Mutation (SNP) | VAF 9/286 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EFTUD2 | c.1255G>T p.V419F | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- EIPR1 | c.42G>T p.Q14H | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.414); called by muse, mutect2
- EML2 | c.1304T>C p.V435A | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- EPHB1 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ERICH3 | c.2622G>T p.E874D | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- FAM167B | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXO41 | c.2183C>T p.T728I | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FOXG1 | c.203C>A p.P68Q | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by muse, varscan2
- FOXO3 | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FOXR1 | c.775C>G p.R259G | Missense Mutation (SNP) | VAF 209/416 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- FRMPD2 | c.533G>T p.R178M | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- FRY | c.3213G>C p.L1071F | Missense Mutation (SNP) | VAF 32/327 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); called by muse, mutect2
- GBP5 | c.215A>C p.Q72P | Missense Mutation (SNP) | VAF 37/364 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GJA10 | c.1076G>T p.G359V | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- GP1BA | c.484C>A p.P162T | Missense Mutation (SNP) | VAF 125/223 reads (56%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- GP1BA | c.485C>A p.P162H | Missense Mutation (SNP) | VAF 126/223 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- H2BW1 | c.491+1G>T p.X164_splice | Splice Site (SNP) | VAF 14/31 reads (45%) | called by muse, varscan2
- HARS2 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 87/577 reads (15%) | called by muse, mutect2, varscan2
- HDAC7 | c.2771C>G p.T924S (on ENST00000427332; = p.T963S on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- HELZ2 | c.7281+1G>T p.X2427_splice (on ENST00000467148 / NM_001037335.2; = p.X1858_splice on NM_033405.3) | Splice Site (SNP) | VAF 11/108 reads (10%) | called by muse, mutect2
- HERC2 | c.9512A>T p.E3171V | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HIPK1 | c.378A>T p.K126N | Missense Mutation (SNP) | VAF 82/1015 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.435); called by muse, mutect2
- HK1 | c.1719+1G>T p.X573_splice | Splice Site (SNP) | VAF 231/784 reads (29%) | called by muse, mutect2, varscan2
- HRG | c.178A>T p.R60* | Nonsense Mutation (SNP) | VAF 82/484 reads (17%) | called by muse, mutect2, varscan2
- HSPA1L | c.331G>C p.G111R | Missense Mutation (SNP) | VAF 42/331 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGLV1-47 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ILDR2 | c.1018A>T p.S340C | Missense Mutation (SNP) | VAF 197/561 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IPO13 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 25/397 reads (6%) | called by muse, mutect2
- IPO8 | c.181A>T p.K61* | Nonsense Mutation (SNP) | VAF 149/269 reads (55%) | called by muse, mutect2, varscan2
- IQCA1 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 138/289 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IRF1 | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 73/260 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JOSD2 | c.468-1G>C p.X156_splice | Splice Site (SNP) | VAF 14/159 reads (9%) | called by muse, mutect2
- KANK1 | c.358A>T p.K120* | Nonsense Mutation (SNP) | VAF 166/668 reads (25%) | called by muse, mutect2, varscan2
- KCNAB2 | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- KIAA0232 | c.3370T>G p.S1124A | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KIF19 | c.2492G>T p.R831L | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- KIF21A | c.1406G>C p.G469A | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- KIF26B | c.4601C>A p.S1534Y | Missense Mutation (SNP) | VAF 122/528 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- KLHL38 | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 15/294 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.044); called by muse, mutect2
- KMO | c.447T>C p.L149= | Splice Region (SNP) | VAF 13/279 reads (5%) | called by muse, mutect2
- KRTAP5-2 | c.124T>A p.C42S | Missense Mutation (SNP) | VAF 39/162 reads (24%) | PolyPhen benign (0.152); called by muse, mutect2, varscan2
- KRTAP6-3 | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 80/256 reads (31%) | PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- LAMB4 | c.2510C>A p.P837H | Missense Mutation (SNP) | VAF 120/516 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- LRBA | c.1726C>G p.P576A | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- LRIT1 | c.483C>A p.D161E | Missense Mutation (SNP) | VAF 25/629 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRRC4B | c.1438G>C p.G480R | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- LRRC71 | c.1065T>A p.N355K | Missense Mutation (SNP) | VAF 34/614 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2
- LRRC8D | c.1444dup p.V482Gfs*7 | Frame Shift Ins (INS) | VAF 156/436 reads (36%) | called by mutect2, pindel, varscan2
- LRRIQ1 | c.1289A>T p.N430I | Missense Mutation (SNP) | VAF 62/107 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRN3 | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- LRSAM1 | c.1534A>T p.S512C | Missense Mutation (SNP) | VAF 46/604 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- LY75 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- LY9 | c.791C>A p.P264Q | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- MAGEF1 | c.844G>C p.D282H | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP2K7 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 100/286 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAP3K4 | c.3535A>T p.M1179L | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, varscan2
- MCM6 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.864); called by muse, mutect2
- MET | c.2546T>A p.M849K | Missense Mutation (SNP) | VAF 89/272 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- METTL22 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- MINDY4 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 155/405 reads (38%) | called by muse, mutect2, varscan2
- MINPP1 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MPPED2 | c.537G>T p.W179C | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- MS4A12 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 127/420 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC5B | c.3454+1G>A p.X1152_splice | Splice Site (SNP) | VAF 69/236 reads (29%) | called by muse, mutect2, varscan2
- MYBBP1A | c.1224_1228del p.W409Afs*14 | Frame Shift Del (DEL) | VAF 50/416 reads (12%) | called by mutect2, pindel, varscan2
- MYCBP2 | c.3493G>T p.A1165S (on ENST00000357337; = p.A1203S on NM_015057.5) | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MYH7B | c.1224C>G p.F408L | Missense Mutation (SNP) | VAF 20/309 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MYL4 | c.545A>G p.N182S | Missense Mutation (SNP) | VAF 76/367 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MYOCD | c.2242G>T p.G748* | Nonsense Mutation (SNP) | VAF 28/245 reads (11%) | called by muse, mutect2, varscan2
- NALCN | c.5103C>A p.C1701* | Nonsense Mutation (SNP) | VAF 84/239 reads (35%) | called by muse, mutect2, varscan2
- NCOR1 | c.4432G>A p.D1478N | Missense Mutation (SNP) | VAF 191/362 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NDUFAF6 | c.851C>G p.A284G | Missense Mutation (SNP) | VAF 59/755 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.364); called by muse, mutect2
- NDUFS1 | c.1198G>T p.V400F | Missense Mutation (SNP) | VAF 284/573 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NEDD4 | c.101G>A p.C34Y | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- NELL1 | c.369T>A p.D123E | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NOBOX | c.1130C>A p.P377H | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- NR5A1 | c.147C>A p.C49* | Nonsense Mutation (SNP) | VAF 132/216 reads (61%) | called by muse, mutect2, varscan2
- OR10C1 | c.726C>A p.C242* (on ENST00000622521; = p.C240* on NM_013941.3) | Nonsense Mutation (SNP) | VAF 45/417 reads (11%) | called by muse, mutect2, varscan2
- OR5AC2 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- OR5D13 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- PAPSS2 | c.639G>T p.Q213H | Missense Mutation (SNP) | VAF 147/535 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB5 | c.1832C>A p.P611H | Missense Mutation (SNP) | VAF 167/634 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDE4DIP | c.475G>T p.V159F | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.029); called by mutect2, varscan2
- PIBF1 | c.2014G>C p.A672P | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- PKHD1L1 | c.3437G>T p.G1146V | Missense Mutation (SNP) | VAF 98/348 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, varscan2
- PKMYT1 | c.961C>G p.P321A | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PPFIA4 | c.-258+1G>T | Splice Site (SNP) | VAF 25/99 reads (25%) | called by muse, mutect2, varscan2
- PPM1L | c.49C>A p.R17S | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PRR14L | c.6399G>A p.M2133I | Missense Mutation (SNP) | VAF 52/273 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PTHLH | c.105A>T p.K35N | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PTPRJ | c.3687T>G p.S1229R | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); called by muse, mutect2
- PUS7L | c.1147A>T p.R383* | Nonsense Mutation (SNP) | VAF 54/194 reads (28%) | called by muse, mutect2, varscan2
- RAD51AP2 | c.893G>T p.W298L | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- REG3G | c.390C>A p.Y130* | Nonsense Mutation (SNP) | VAF 39/317 reads (12%) | called by muse, mutect2, varscan2
- RELN | c.8747C>T p.T2916I | Missense Mutation (SNP) | VAF 146/515 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- RGL2 | c.797A>T p.Q266L | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- RILP | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2
- RPE65 | c.870T>G p.H290Q | Missense Mutation (SNP) | VAF 30/551 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RUSF1 | c.1308A>T p.K436N | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.021); called by muse, mutect2
- SBNO2 | c.1701_1704+2del p.X567_splice | Splice Site (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel, varscan2
- SCN8A | c.4456A>G p.K1486E | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2
- SEMA6C | c.961A>T p.T321S | Missense Mutation (SNP) | VAF 198/416 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SERINC1 | c.295A>T p.M99L | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SERPINB11 | c.895T>A p.S299T | Missense Mutation (SNP) | VAF 22/341 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2
- SETMAR | c.860G>T p.C287F | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC9A6 | c.1887G>T p.L629F | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- SNED1 | c.2952G>C p.K984N | Missense Mutation (SNP) | VAF 13/421 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- SNTG1 | c.11G>T p.R4I | Missense Mutation (SNP) | VAF 93/226 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- SOBP | c.2182C>T p.R728C | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.335); called by muse, mutect2
- SOHLH1 | c.193C>G p.R65G | Missense Mutation (SNP) | VAF 102/251 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SORCS1 | c.3079G>T p.G1027C | Missense Mutation (SNP) | VAF 62/381 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPON1 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 95/343 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPON1 | c.2360G>A p.S787N | Missense Mutation (SNP) | VAF 63/375 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SPSB4 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SRSF4 | c.1059G>T p.K353N | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); called by muse, varscan2
- STATH | c.40G>T p.V14F | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- STK32A | c.210G>T p.K70N | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STK36 | c.2527C>G p.P843A | Missense Mutation (SNP) | VAF 21/441 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SULF2 | c.2548T>A p.W850R | Missense Mutation (SNP) | VAF 39/355 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAB2 | c.1505A>C p.N502T | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- TAGAP | c.1209C>A p.D403E | Missense Mutation (SNP) | VAF 61/373 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- TAS2R40 | c.446C>A p.S149* | Nonsense Mutation (SNP) | VAF 104/494 reads (21%) | called by muse, mutect2, varscan2
- TBC1D12 | c.506del p.Y169Sfs*111 | Frame Shift Del (DEL) | VAF 17/130 reads (13%) | called by mutect2, pindel, varscan2
- TBX18 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 40/393 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- TBX4 | c.857C>A p.A286D | Missense Mutation (SNP) | VAF 100/684 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- TEAD2 | c.16del p.A6Lfs*63 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | called by mutect2, pindel
- TEP1 | c.1750G>T p.A584S | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- TERT | c.1573+7_1573+9del | Splice Region (DEL) | VAF 120/258 reads (47%) | called by pindel, varscan2
- TF | c.200G>A p.C67Y | Missense Mutation (SNP) | VAF 41/711 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TG | c.5954C>T p.S1985F | Missense Mutation (SNP) | VAF 16/594 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.383); called by muse, mutect2
- TLN1 | c.7576C>T p.R2526W | Missense Mutation (SNP) | VAF 59/307 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAPPC9 | c.148C>A p.Q50K | Missense Mutation (SNP) | VAF 47/1209 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.194); called by muse, mutect2
- TRAV30 | c.149A>G p.Y50C | Missense Mutation (SNP) | VAF 15/300 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); called by muse, mutect2
- TRBC2 | c.404C>A p.S135Y | Missense Mutation (SNP) | VAF 116/500 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- TRIO | c.8377G>C p.D2793H | Missense Mutation (SNP) | VAF 172/405 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- TTC7B | c.2482G>T p.E828* | Nonsense Mutation (SNP) | VAF 61/125 reads (49%) | called by muse, mutect2, varscan2
- TUT4 | c.3101T>G p.L1034W | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC5B | c.1478G>T p.G493V | Missense Mutation (SNP) | VAF 75/261 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- VN1R2 | c.404A>T p.D135V | Missense Mutation (SNP) | VAF 89/214 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- VPS13D | c.7914G>T p.L2638F | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- VSIR | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 25/112 reads (22%) | called by muse, mutect2
- WDR97 | c.4673T>G p.M1558R | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- ZBBX | c.433-2A>T p.X145_splice | Splice Site (SNP) | VAF 68/145 reads (47%) | called by muse, mutect2, varscan2
- ZBED2 | c.284C>A p.T95N | Missense Mutation (SNP) | VAF 65/407 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- ZBTB1 | c.1211A>G p.N404S | Missense Mutation (SNP) | VAF 63/378 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF420 | c.1668G>C p.E556D | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2
- ZNF608 | c.1354A>T p.T452S | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZSCAN30 | c.1360T>A p.S454T | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZSCAN9 | c.75G>T p.M25I | Missense Mutation (SNP) | VAF 69/421 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM12 | c.2449C>A p.R817= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as rs769115498, COSV64133210; called by muse, mutect2, varscan2
- ADCY8 | c.2877G>T p.V959= | Silent (SNP) | VAF 79/382 reads (21%) | called by muse, mutect2, varscan2
- ADGRL3 | c.4638G>A p.Q1546= (on ENST00000506720 / NM_001322402.2; = p.Q1435= on NM_015236.6) | Silent (SNP) | VAF 94/286 reads (33%) | catalogued as COSV72231167; called by muse, mutect2, varscan2
- AGXT | c.666C>T p.F222= | Silent (SNP) | VAF 12/330 reads (4%) | called by muse, mutect2
- AKAP13 | c.549G>T p.L183= | Silent (SNP) | VAF 54/159 reads (34%) | called by muse, mutect2, varscan2
- ARRDC3 | c.468T>C p.F156= | Silent (SNP) | VAF 71/237 reads (30%) | called by muse, mutect2, varscan2
- BHLHE22 | c.135C>G p.S45= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs1398063855; called by muse, mutect2, varscan2
- BRIP1 | c.1314A>T p.L438= | Silent (SNP) | VAF 72/552 reads (13%) | called by muse, mutect2, varscan2
- C1QTNF1 | c.214C>A p.R72= | Silent (SNP) | VAF 183/448 reads (41%) | catalogued as COSV59263416; called by mutect2, varscan2
- C5orf38 | c.309G>C p.A103= | Silent (SNP) | VAF 25/286 reads (9%) | catalogued as COSV100121964, COSV57411261; called by muse, mutect2
- CCND3 | c.681G>A p.E227= | Silent (SNP) | VAF 128/300 reads (43%) | called by muse, mutect2, varscan2
- CD1E | c.768A>T p.R256= | Silent (SNP) | VAF 123/257 reads (48%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.2187C>A p.A729= | Silent (SNP) | VAF 182/804 reads (23%) | catalogued as COSV62182944; called by muse, mutect2, varscan2
- CPA2 | c.216C>A p.V72= | Silent (SNP) | VAF 88/413 reads (21%) | called by muse, mutect2, varscan2
- DDX3X | c.786C>G p.R262= (on ENST00000399959; = p.R263= on NM_001356.5) | Silent (SNP) | VAF 9/111 reads (8%) | called by muse, mutect2
- DIDO1 | c.2976G>A p.V992= | Silent (SNP) | VAF 33/261 reads (13%) | called by muse, mutect2, varscan2
- DNAH5 | c.12984G>C p.L4328= | Silent (SNP) | VAF 56/1243 reads (5%) | called by muse, mutect2
- DST | c.11910A>T p.S3970= (on ENST00000361203 / NM_001374722.1; = p.S1558= on NM_015548.5) | Silent (SNP) | VAF 29/198 reads (15%) | catalogued as COSV55005965, COSV99761026; called by muse, mutect2, varscan2
- ECE1 | c.444C>T p.T148= | Silent (SNP) | VAF 60/784 reads (8%) | called by muse, mutect2
- FAM47A | c.663C>T p.S221= | Silent (SNP) | VAF 69/133 reads (52%) | called by muse, mutect2, varscan2
- FLT4 | c.1485G>A p.Q495= | Silent (SNP) | VAF 208/630 reads (33%) | called by muse, mutect2, varscan2
- GRIK4 | c.564G>T p.T188= | Silent (SNP) | VAF 112/220 reads (51%) | catalogued as rs758395240, COSV70805378; called by muse, mutect2, varscan2
- HMCN1 | c.10542A>G p.E3514= | Silent (SNP) | VAF 15/149 reads (10%) | called by muse, mutect2
- HMG20B | c.255C>T p.R85= | Silent (SNP) | VAF 106/273 reads (39%) | catalogued as COSV53572659; called by muse, mutect2, varscan2
- IFNA8 | c.369G>A p.V123= | Silent (SNP) | VAF 139/591 reads (24%) | catalogued as rs778084720; called by muse, mutect2, varscan2
- ITGAL | c.1089A>G p.A363= | Silent (SNP) | VAF 92/298 reads (31%) | called by muse, mutect2, varscan2
- KANK1 | c.2475C>T p.H825= | Silent (SNP) | VAF 32/123 reads (26%) | catalogued as rs1465149483; called by muse, mutect2, varscan2
- KIF15 | c.3255G>T p.L1085= | Silent (SNP) | VAF 56/235 reads (24%) | called by muse, mutect2, varscan2
- KLK15 | c.642C>A p.V214= | Silent (SNP) | VAF 41/100 reads (41%) | called by muse, mutect2, varscan2
- KMT2C | c.2430C>T p.N810= | Silent (SNP) | VAF 53/530 reads (10%) | catalogued as COSV51432160; called by muse, mutect2, varscan2
- LAMA2 | c.5283C>A p.S1761= | Silent (SNP) | VAF 89/266 reads (33%) | called by muse, mutect2, varscan2
- LRRC4B | c.1875C>A p.P625= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs776283499, COSV100976097, COSV65350623; called by muse, mutect2, varscan2
- LY9 | c.609A>T p.G203= | Silent (SNP) | VAF 39/873 reads (4%) | called by muse, mutect2
- LYZL6 | c.405C>A p.G135= | Silent (SNP) | VAF 47/335 reads (14%) | catalogued as rs1568418159; called by muse, mutect2, varscan2
- MAGEL2 | c.726T>A p.P242= | Silent (SNP) | VAF 61/210 reads (29%) | called by muse, mutect2, varscan2
- MAP3K11 | c.1893C>T p.R631= | Silent (SNP) | VAF 156/349 reads (45%) | catalogued as rs775882150, COSV58418551; called by muse, mutect2, varscan2
- MCF2L2 | c.1569G>C p.L523= | Silent (SNP) | VAF 20/342 reads (6%) | called by muse, mutect2
- MEFV | c.12C>A p.T4= | Silent (SNP) | VAF 107/627 reads (17%) | called by muse, mutect2, varscan2
- MGAT1 | c.381T>C p.H127= | Silent (SNP) | VAF 13/113 reads (12%) | called by mutect2, varscan2
- MTA2 | c.588G>C p.V196= | Silent (SNP) | VAF 46/207 reads (22%) | called by muse, mutect2, varscan2
- MYO18A | c.5202G>C p.L1734= | Silent (SNP) | VAF 61/171 reads (36%) | called by muse, mutect2, varscan2
- NID2 | c.1230C>T p.T410= | Silent (SNP) | VAF 36/493 reads (7%) | catalogued as rs889650106; called by muse, mutect2
- NLRP7 | c.840C>T p.P280= | Silent (SNP) | VAF 144/312 reads (46%) | catalogued as rs1463547718, COSV60174386; called by muse, mutect2, varscan2
- NYNRIN | c.352C>T p.L118= | Silent (SNP) | VAF 55/370 reads (15%) | called by muse, mutect2, varscan2
- OR2A4 | c.627C>A p.P209= | Silent (SNP) | VAF 86/1232 reads (7%) | called by muse, varscan2
- OR2T35 | c.391C>A p.R131= | Silent (SNP) | VAF 11/75 reads (15%) | called by mutect2, varscan2
- OR4X2 | c.714G>A p.V238= | Silent (SNP) | VAF 50/235 reads (21%) | called by muse, mutect2, varscan2
- OR5T3 | c.633C>T p.L211= | Silent (SNP) | VAF 34/252 reads (13%) | called by muse, varscan2
- OTOA | c.1188C>G p.T396= (on ENST00000286149; = p.T382= on NM_144672.4) | Silent (SNP) | VAF 119/632 reads (19%) | called by muse, mutect2, varscan2
- P3H2 | c.921G>T p.L307= | Silent (SNP) | VAF 105/476 reads (22%) | catalogued as COSV60021589; called by muse, mutect2, varscan2
- PANK2 | c.243G>C p.A81= | Silent (SNP) | VAF 40/178 reads (22%) | called by muse, mutect2
- PLEKHD1 | c.1290C>T p.A430= | Silent (SNP) | VAF 200/521 reads (38%) | called by muse, mutect2, varscan2
- PLEKHG5 | c.1089G>T p.G363= (on ENST00000400915 / NM_001042663.3; = p.G326= on NM_020631.6) | Silent (SNP) | VAF 120/518 reads (23%) | catalogued as rs1327754548; called by muse, mutect2, varscan2
- PLEKHS1 | c.1158C>T p.I386= | Silent (SNP) | VAF 33/192 reads (17%) | called by muse, mutect2, varscan2
- PNLIP | c.465G>T p.A155= | Silent (SNP) | VAF 74/407 reads (18%) | called by muse, mutect2, varscan2
- PODXL | c.1317G>A p.G439= (on ENST00000378555 / NM_001018111.3; = p.G407= on NM_005397.4) | Silent (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- PPFIA4 | c.1803G>T p.A601= (on ENST00000447715; = p.A602= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 107/355 reads (30%) | catalogued as COSV55311048; called by muse, mutect2, varscan2
- PRDM13 | c.303C>G p.V101= | Silent (SNP) | VAF 28/339 reads (8%) | called by muse, mutect2
- PTPN5 | c.174A>T p.P58= | Silent (SNP) | VAF 32/137 reads (23%) | called by muse, mutect2, varscan2
- RABGAP1 | c.432C>T p.S144= | Silent (SNP) | VAF 18/352 reads (5%) | catalogued as rs1324906944, COSV100438427; called by muse, mutect2
- RFPL4A | c.513T>A p.S171= | Silent (SNP) | VAF 424/797 reads (53%) | called by muse, mutect2, varscan2
- RHOT2 | c.1017G>C p.A339= | Silent (SNP) | VAF 27/193 reads (14%) | catalogued as COSV53469616; called by muse, varscan2
- RPIA | c.531C>T p.G177= | Silent (SNP) | VAF 21/799 reads (3%) | called by muse, mutect2
- RTL4 | c.102G>A p.T34= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as rs772746579, COSV100466199, COSV61207144; called by muse, mutect2, varscan2
- SAMSN1 | c.546C>G p.A182= | Silent (SNP) | VAF 68/391 reads (17%) | called by muse, mutect2, varscan2
- SCYL1 | c.864C>T p.A288= | Silent (SNP) | VAF 78/161 reads (48%) | catalogued as rs756331964, COSV54214445; called by muse, mutect2, varscan2
- SIGLEC8 | c.1092C>A p.V364= | Silent (SNP) | VAF 94/242 reads (39%) | called by muse, mutect2, varscan2
- SLC15A1 | c.1164C>G p.V388= | Silent (SNP) | VAF 140/395 reads (35%) | catalogued as COSV64732633; called by muse, mutect2, varscan2
- SLC34A1 | c.1326G>A p.P442= | Silent (SNP) | VAF 91/548 reads (17%) | catalogued as rs767726771, COSV60998165; called by muse, mutect2, varscan2
- SLC38A8 | c.486G>A p.L162= | Silent (SNP) | VAF 28/365 reads (8%) | called by muse, mutect2
- SLC6A2 | c.573C>A p.L191= | Silent (SNP) | VAF 97/218 reads (44%) | catalogued as COSV99573584; called by muse, mutect2, varscan2
- SLC6A2 | c.1599T>C p.V533= | Silent (SNP) | VAF 76/805 reads (9%) | called by muse, mutect2
- SNX6 | c.789A>G p.S263= (on ENST00000652385; = p.S135= on NM_021249.5) | Silent (SNP) | VAF 14/252 reads (6%) | catalogued as rs1356302807; called by muse, mutect2
- SPATA18 | c.597G>A p.E199= | Silent (SNP) | VAF 152/484 reads (31%) | called by muse, mutect2, varscan2
- SST | c.129G>T p.A43= | Silent (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2, varscan2
- STON2 | c.27C>A p.A9= | Silent (SNP) | VAF 74/252 reads (29%) | catalogued as COSV50851554; called by muse, mutect2, varscan2
- TAF1L | c.9C>A p.P3= | Silent (SNP) | VAF 38/160 reads (24%) | catalogued as COSV54260176; called by muse, mutect2, varscan2
- TEX15 | c.6915C>T p.I2305= (on ENST00000256246; = p.I2688= on NM_001350162.2) | Silent (SNP) | VAF 28/413 reads (7%) | called by muse, mutect2
- TMEM176B | c.285C>A p.A95= | Silent (SNP) | VAF 59/193 reads (31%) | called by muse, mutect2, varscan2
- TMTC1 | c.2073A>T p.A691= (on ENST00000539277 / NM_001193451.2; = p.A583= on NM_175861.3) | Silent (SNP) | VAF 80/369 reads (22%) | called by muse, mutect2, varscan2
- TVP23A | c.265C>A p.R89= | Silent (SNP) | VAF 27/225 reads (12%) | called by muse, mutect2, varscan2
- UBTF | c.1818C>A p.R606= | Silent (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- WARS1 | c.396G>A p.L132= | Silent (SNP) | VAF 62/190 reads (33%) | catalogued as rs568328469; called by muse, varscan2
- ZBTB40 | c.345C>T p.S115= | Silent (SNP) | VAF 86/630 reads (14%) | catalogued as rs562984834; called by muse, mutect2, varscan2
- ZNF208 | c.3708G>T p.T1236= | Silent (SNP) | VAF 48/188 reads (26%) | catalogued as rs368192167; called by muse, mutect2, varscan2
- ZNF37A | c.708C>T p.T236= | Silent (SNP) | VAF 15/320 reads (5%) | called by muse, mutect2
- AC005863.1 | n.242G>C | RNA (SNP) | VAF 32/221 reads (14%) | called by muse, mutect2
- AGXT | c.847-211del | Intron (DEL) | VAF 14/142 reads (10%) | called by mutect2, varscan2
- AP000769.5 | chr11:65498581 C>T | 5'Flank (SNP) | VAF 79/206 reads (38%) | called by muse, mutect2, varscan2
- ATF2 | c.1185+458C>T | Intron (SNP) | VAF 36/142 reads (25%) | catalogued as rs946347718; called by muse, mutect2, varscan2
- BRCA1 | c.*568A>T | 3'UTR (SNP) | VAF 136/450 reads (30%) | called by muse, mutect2, varscan2
- C22orf15 | c.-11C>A | 5'UTR (SNP) | VAF 44/262 reads (17%) | called by muse, mutect2, varscan2
- C2orf83 | n.310del | RNA (DEL) | VAF 259/499 reads (52%) | called by mutect2, pindel, varscan2
- CCDC85C | c.*11582A>G | 3'UTR (SNP) | VAF 82/210 reads (39%) | called by muse, mutect2, varscan2
- CDH2 | c.173-22625G>T | Intron (SNP) | VAF 68/253 reads (27%) | catalogued as COSV52295218; called by muse, mutect2, varscan2
- CDH23 | c.3369+397C>A | Intron (SNP) | VAF 132/548 reads (24%) | called by muse, mutect2, varscan2
- CEROX1 | n.3168C>G | RNA (SNP) | VAF 23/118 reads (19%) | called by muse, mutect2
- CHD2 | c.62+3613C>G | Intron (SNP) | VAF 10/240 reads (4%) | called by muse, mutect2
- CLCN3 | c.2367-2040G>C | Intron (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
- CPLANE1 | chr5:37169165 T>A | 3'Flank (SNP) | VAF 39/339 reads (12%) | called by muse, mutect2, varscan2
- CPNE7 | c.1764+287C>A | Intron (SNP) | VAF 76/243 reads (31%) | called by muse, mutect2, varscan2
- CPNE7 | c.1764+288C>A | Intron (SNP) | VAF 76/242 reads (31%) | called by muse, mutect2, varscan2
- CRTAM | c.-8A>T | 5'UTR (SNP) | VAF 113/248 reads (46%) | called by muse, mutect2, varscan2
- CYP21A1P | chr6:32009626 A>T | 3'Flank (SNP) | VAF 173/812 reads (21%) | called by muse, mutect2, varscan2
- CYP4F8 | c.343+153C>A | Intron (SNP) | VAF 95/257 reads (37%) | called by muse, mutect2, varscan2
- DNAH14 | c.3537+2533G>T | Intron (SNP) | VAF 45/240 reads (19%) | catalogued as rs866413222; called by muse, mutect2, varscan2
- EAPP | c.74+224G>T | Intron (SNP) | VAF 77/132 reads (58%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+8187A>T | Intron (SNP) | VAF 59/236 reads (25%) | catalogued as rs767117156; called by muse, mutect2, varscan2
- FAM27E5 | n.264C>A | RNA (SNP) | VAF 44/136 reads (32%) | called by muse, mutect2, varscan2
- FAM86DP | n.696G>T | RNA (SNP) | VAF 238/965 reads (25%) | catalogued as rs1285870524; called by muse, varscan2
- FMR1 | c.*297G>A | 3'UTR (SNP) | VAF 18/124 reads (15%) | called by muse, mutect2, varscan2
- GFUS | c.391-29A>T | Intron (SNP) | VAF 25/171 reads (15%) | called by muse, mutect2, varscan2
- GORAB | c.*733A>G | 3'UTR (SNP) | VAF 25/77 reads (32%) | catalogued as rs551216505; called by muse, mutect2, varscan2
- IGF2 | c.-4+184C>A | Intron (SNP) | VAF 46/182 reads (25%) | catalogued as COSV56098562; called by muse, mutect2, varscan2
- JPH3 | chr16:87702152 C>G | 3'Flank (SNP) | VAF 22/507 reads (4%) | catalogued as rs1055354525; called by muse, mutect2
- LIMS2 | c.172-30G>C | Intron (SNP) | VAF 49/391 reads (13%) | called by muse, mutect2, varscan2
- LINC01591 | n.167G>A | RNA (SNP) | VAF 47/130 reads (36%) | catalogued as rs757258503; called by muse, mutect2, varscan2
- LRP1B | c.13247+895C>A | Intron (SNP) | VAF 85/291 reads (29%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5237C>A | Intron (SNP) | VAF 111/573 reads (19%) | catalogued as COSV99962653; called by muse, mutect2, varscan2
- METTL22 | c.772+12G>T | Intron (SNP) | VAF 46/280 reads (16%) | called by muse, mutect2, varscan2
- MIF | c.281+23G>C | Intron (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- MPRIP | c.2164-4129G>T | Intron (SNP) | VAF 104/458 reads (23%) | called by muse, mutect2, varscan2
- MYH11 | c.633+1919C>A | Intron (SNP) | VAF 33/185 reads (18%) | called by muse, mutect2, varscan2
- OCLNP1 | n.79G>T | RNA (SNP) | VAF 74/352 reads (21%) | called by muse, varscan2
- PARP1 | c.2406+13G>T | Intron (SNP) | VAF 126/517 reads (24%) | called by muse, mutect2, varscan2
- PDS5B | c.*652dup | 3'UTR (INS) | VAF 40/145 reads (28%) | called by mutect2, pindel, varscan2
- PPT2 | chr6:32153524 G>T | 5'Flank (SNP) | VAF 128/334 reads (38%) | called by muse, mutect2, varscan2
- PTPN20CP | n.691C>A | RNA (SNP) | VAF 107/936 reads (11%) | catalogued as rs576633117; called by muse, varscan2
- PTPN20CP | n.690C>A | RNA (SNP) | VAF 104/946 reads (11%) | catalogued as rs1564402645; called by muse, varscan2
- PTPRVP | n.4144-22C>T | Intron (SNP) | VAF 42/201 reads (21%) | called by muse, mutect2, varscan2
- RAB11B | chr19:8390338 G>A | 5'Flank (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- RARRES1 | chr3:158733951 A>C | 5'Flank (SNP) | VAF 28/250 reads (11%) | called by muse, mutect2, varscan2
- RASGRP2 | c.371+23G>C | Intron (SNP) | VAF 91/618 reads (15%) | called by muse, mutect2, varscan2
- SEPSECS | c.548-20T>A | Intron (SNP) | VAF 16/400 reads (4%) | called by muse, mutect2
- SEPTIN9 | c.*293G>T | 3'UTR (SNP) | VAF 147/368 reads (40%) | called by muse, mutect2
- SLC25A13 | c.*263A>G | 3'UTR (SNP) | VAF 58/1030 reads (6%) | called by muse, mutect2
- SLC25A13 | c.*261T>C | 3'UTR (SNP) | VAF 58/1016 reads (6%) | called by muse, mutect2
- SNORD114-9 | n.51T>C | RNA (SNP) | VAF 34/125 reads (27%) | called by muse, mutect2, varscan2
- TAAR3P | n.534G>T | RNA (SNP) | VAF 37/239 reads (15%) | called by muse, mutect2, varscan2
- TRDC | c.*197G>A | 3'UTR (SNP) | VAF 16/141 reads (11%) | called by muse, mutect2, varscan2
- USH1C | c.1285-18C>A | Intron (SNP) | VAF 23/95 reads (24%) | called by muse, mutect2, varscan2
- VIPR2 | c.51+358G>T | Intron (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- XAF1 | c.-24C>A | 5'UTR (SNP) | VAF 47/292 reads (16%) | called by muse, mutect2, varscan2
- ZCWPW2 | c.493-480C>T | Intron (SNP) | VAF 22/81 reads (27%) | called by muse, mutect2, varscan2
- ZFHX3 | c.-851T>A | 5'UTR (SNP) | VAF 75/183 reads (41%) | called by muse, mutect2, varscan2
- ZNF733P | n.55A>T | RNA (SNP) | VAF 59/243 reads (24%) | called by muse, mutect2, varscan2
- ZNF783 | c.802+3445G>T | Intron (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
